Surgical pathology report (de-identified scan), TCGA case TCGA-ZG-A9M4, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University Medical Center Hamburg-Eppendorf, specimen TCGA-ZG-A9M4-01A (Primary Tumor).

[page 1 of 3]
Histopathological Report

Date of cancer sample procurement:

Date of pathology report:

Patient ID:

Gross description:

1. (Prostate gland): Prostate gland: Weight: 30.9 g, Volume: 25 ml, Size: 4 x 5 x 3.5 cm. On the ventral side a 2.5 x 1 cm measuring tissue defect marked with yellow ink. Apical peri-urethral a funnel shaped 1.7 x 1.4 cm tissue defect marked with red ink. Total of the cross sections: 0.8 cm.
2. (Lymph nodes, right side): 6.5 x 5.5 x 1.4 cm measuring adipose tissue containing 7 nodes measuring up to 4.6 cm.
3. (Lymph nodes, left side): 6.3 x 5.3 x 1.3 cm measuring adipose tissue containing 5 nodes measuring up to 4.5 cm.

Microscopy:

1. Apex right and left: Right 7 tissue blocks, left 6 tissue blocks (total 13 tissue blocks). 2 cross sections: Right 8 tissue blocks, left 8 tissue blocks (total 16 tissue blocks). Basis right and left: Right 8 tissue blocks, left 7 tissue blocks (total 15 tissue blocks). Seminal vesicles right and left: Right 4 tissue blocks, left 2 tissue blocks (total 6 tissue blocks). Deferent ducts right and left: Right 1 tissue block, left 1 tissue block (total 2 tissue blocks).
2. Frozen lymph nodes right: 13 tissue blocks.
3. Frozen lymph nodes left: 11 tissue blocks.

ICD-O-3

Adenocarcinoma NOS 8140/3

Site: Prostate NOS C61.9

9/21/23/14

Diagnosis:

1. (Prostate gland): Poorly differentiated prostatic adenocarcinoma, Gleason 5+4=9, (Gleason 5: 90%, Gleason 4: 10%). Tumor involves both lobes with the main focus around the apex. Maximum tumor diameter: 28 mm. Perineural invasion. Tumor infiltration into peri-prostatic adipose tissue in 3 tissue blocks with the main focus around the right seminal vesicle (maximum invasion length 1.4 mm, maximal invasion depth 0.9 mm). Tumor infiltration into both seminal vesicles. Positive surgical margin around the right seminal vesicle (contact length: 0.2mm; Gleason 5).

Remaining prostatic tissue with small foci of prostatic intraepithelial neoplasia (high grade PIN) and signs of myoglandular hyperplasia of the prostate. Urothelium of the prostatic urethra without dysplasia. Tumor-free deferent ducts.

2. (Lymph nodes, right side): Five tumor-free lymph nodes (0/5).
3. (Lymph nodes, left side): One lymph node metastasis (1.2 mm) in three lymph nodes (1/3).

[page 2 of 3]
Tumor classification

(in consideration of the immunohistochemical analyses):

pT3b, Gleason 5+4=9 (Gleason 5: 90%, Gleason 4: 10%). maximum tumor diameter: 28 mm, tumor volume approx. 10.0 ml (Gleason 5: 9.0 ml, Gleason 4: 1.0 ml), pN1 (1/8), L1, V0, R1

Comments:

Positive surgical margin in tissue block SBR4.

Tumor infiltration into peri-prostatic adipose tissue in tissue blocks SBR1, SBR2 and SBR4.

The parallel sample showed more adenocarcinoma in the secondary resection of the ventral bladder neck.

Immunohistochemical analyses (AE1/AE3, PSA) on three lymph nodes (tissue blocks 2G, 2E, 3F) revealed one 1.2mm measuring on the left side.

Immunohistochemical analyses (D2-40, CD31) on tissue blocks SBR2 and SBR4 revealed lymphatic but no venous invasion.

One macroscopic image for tumor mapping.

*Per dx discrepancy form, TCGA
tumor is Gleason 5+5.*

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Gleason 5+4	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Gleason 5+5	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Frozen sample tissue block submitted to TCGA has a different Gleason score than the frozen tissue block that was used for diagnosis.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file b67c9a90-08a2-4685-a572-df3d388dda50 (TCGA-ZG-A9M4.86764ADF-5B8B-4989-99AA-595616A115A4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).